TCGA case TCGA-AL-3466 — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Fox Chase. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9fc40b03-0b56-4b1f-93ed-dbc455ae3fd9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 41 years; Vital status: Dead; Days to death: 293 days.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 41.6 years (15,181 days); Year of diagnosis: 2004; AJCC staging edition: 6th; AJCC clinical T: T3b; AJCC clinical N: N1; AJCC clinical M: M1; AJCC clinical stage: Stage IV; AJCC pathologic T: T3b; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 2.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Interferon; Treatment intent type: Adjuvant; Days to treatment start: 33 days; Days to treatment end: 138 days; Prescribed dose: 10; Route of administration: Subcutaneous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 169 days; Days to treatment end: 169 days; Treatment dose: 1,800 cGy; Course number: 1; Number of fractions: 1; Treatment anatomic sites: Distant Site.
2. Metastasis of diagnosis 1 (Papillary adenocarcinoma, NOS). Age at diagnosis: 41.9 years (15,319 days); Days to diagnosis: 138 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 147 days; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Day 138 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 138 days.
- Days to follow up: 293 days; Disease response: With Tumor.
- Karnofsky performance status: 0.

Molecular and laboratory tests
- Calcium: Normal.
- Leukocytes: Low.
- Platelets: Normal.
- Hemoglobin: Low.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 70 kg; Height: 175 cm; BMI: 22.9.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 10; Tobacco smoking quit year: 2001.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AL-3466-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.3.
  Slide TCGA-AL-3466-01A-01-BS1: Section location: Top; Percent tumor cells: 87; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 10.
  Slide TCGA-AL-3466-01A-01-TS1: Section location: Top; Percent tumor cells: 89; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 10.
  Slide TCGA-AL-3466-01A-02-BS2: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10.
- Sample TCGA-AL-3466-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AL-3466-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; White cell count: Low; Lymph nodes examined: Yes; Tobacco smoking history indicator: 4.
- Drug treatment: Regimen number: 1.
- Drug treatment, Route of administrations: Route of administration: SC.
- Radiation treatment: Therapy regimen: Recurrence.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No; New tumor event surgery met: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 293 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 293 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 138 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AL-3466-01A-01D-1190-01): tumor purity 0.64, ploidy 3.66, whole-genome doublings 1.
